Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A434, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A434-01A (Primary Tumor).

Procurement Date: Laterality: Papillary carcinoma

Path Report: Tumor type:

Papillary carcinoma

Tumor size:

0.7 x 0.7 x 0.7

Laterality:

Left

Focality:

Unifocal

Extrathyroidal extension:

No

Markers and special stains:

Additional comments: No Lymph nodes examined

Reviewed: initials		

7/30/12

ICD-O3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

8-3-12
RD

Source: NCI Genomic Data Commons file 677380e8-a969-451d-8903-c00bb003becd (TCGA-E8-A434.CA8D2EDB-85CA-4F57-8357-17B2D0E702C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).